Gene-level copy-number profile of tumor specimen TCGA-24-1417-01A from TCGA case TCGA-24-1417, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IV; Tumor grade: G3; Age at diagnosis: 54.1 years (19,775 days).
Specimen TCGA-24-1417-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.e5155eb2-5577-4e7a-9549-2ca02076e56d.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-24-1417-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/45a5c813-40f9-4cda-9bf7-0526939216f1

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 16; copy number 1: 1,675; copy number 2: 18,773; copy number 3: 19,873; copy number 4: 11,956; copy number 5: 3,237; copy number 6: 2,706; copy number 7: 764; copy number 8: 813.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-24-1417-01A-01D-0472-01): tumor purity 0.69, ploidy 3.05, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 8 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr12:97,430,884–97,598,415, 8 genes (within-gene range 0–3): RMST, MIR1251, AC007351.2, AC007351.3, AC007351.4, AC007351.1, AC018659.4, AC018659.3.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,577 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:162,486,541–198,222,513, 645 genes, copy number 7–8 (broad region; genes not listed).
- chr7:132,648,794–146,050,366, 360 genes, copy number 7 (broad region; genes not listed).
- chr8:98,371,228–98,942,827, 1 gene, copy number 8 (within-gene range 4–8): STK3.
- chr8:98,436,669–113,436,939, 223 genes, copy number 7–8 (within-gene range 5–8) (broad region; genes not listed).
- chr9:14,475–26,118,408, 348 genes, copy number 8 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,674. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
